Somatic mutation profile of tumor specimen C3N-04157-02 (aliquot CPT0251180006) from CPTAC case C3N-04157, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 61.6 years (22,497 days).
Specimen C3N-04157-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) be2991ea-2139-4fe4-ab5c-57ff78a9f17d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04157-71 (Blood Derived Normal), aliquot CPT0251290002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ba271af8-9810-45b8-a752-e3f4581566b0

The open-access MAF lists 237 somatic variants for this specimen: 168 protein-altering or splice-affecting, 47 silent, 22 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 139, Silent 47, Nonsense Mutation 15, Intron 12, 3'UTR 6, Frame Shift Del 6, Splice Site 5, 5'UTR 2, 5'Flank 1, RNA 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 65/217 reads (30%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.103G>T p.A35S | Missense Mutation (SNP) | VAF 117/576 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.03); catalogued as rs758036438, COSV62791329; called by muse, mutect2, varscan2
- AMMECR1L | c.649A>T p.I217F | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV55760712; called by muse, mutect2
- ANOS1 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs746481142; called by muse, mutect2, varscan2
- ARL2BP | c.440C>T p.S147L | Missense Mutation (SNP) | VAF 16/317 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1183324386; called by muse, mutect2
- ASXL1 | c.1696G>T p.E566* | Nonsense Mutation (SNP) | VAF 51/446 reads (11%) | catalogued as COSV100038917; called by muse, mutect2, varscan2
- AXIN1 | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 83/448 reads (19%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV99249053; called by muse, mutect2, varscan2
- BEST2 | c.389G>T p.R130L | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99244329; called by muse, mutect2, varscan2
- BTNL2 | c.460G>T p.G154* | Nonsense Mutation (SNP) | VAF 25/152 reads (16%) | catalogued as rs757932339; called by muse, mutect2
- C19orf47 | c.622G>A p.E208K | Missense Mutation (SNP) | VAF 28/268 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63508452; called by muse, mutect2, varscan2
- C2orf78 | c.1430C>A p.T477N | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.885); catalogued as rs957165605; called by muse, mutect2, varscan2
- COL16A1 | c.1309C>G p.P437A | Missense Mutation (SNP) | VAF 22/149 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV99593489; called by muse, mutect2, varscan2
- DNMT1 | c.251C>T p.S84F | Missense Mutation (SNP) | VAF 47/430 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.899); catalogued as COSV61580886; called by muse, mutect2, varscan2
- DQX1 | c.1547G>T p.R516L | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as rs369369781; called by muse, mutect2, varscan2
- ENPP2 | c.487C>A p.R163S | Missense Mutation (SNP) | VAF 43/109 reads (39%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV50010797; called by muse, mutect2, varscan2
- ERICH3 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755547640; called by muse, mutect2, varscan2
- EYS | c.3427C>A p.H1143N | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV65486432; called by muse, mutect2, varscan2
- F5 | c.5069C>G p.S1690C | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63122701; called by muse, mutect2
- FBLN2 | c.982G>A p.A328T | Missense Mutation (SNP) | VAF 135/555 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs1338061241; called by muse, mutect2, varscan2
- FOXK2 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 45/67 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs941824225, COSV58878163; called by muse, mutect2, varscan2
- FSIP2 | c.16315C>A p.L5439I | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.578); catalogued as COSV58096985; called by muse, mutect2, varscan2
- GRM1 | c.429C>G p.D143E | Missense Mutation (SNP) | VAF 45/380 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV51252880; called by muse, mutect2, varscan2
- GRM6 | c.1830C>A p.Y610* | Nonsense Mutation (SNP) | VAF 67/429 reads (16%) | catalogued as COSV51444642; called by muse, mutect2, varscan2
- HEG1 | c.842C>T p.S281L | Missense Mutation (SNP) | VAF 38/140 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs1291400102; called by muse, mutect2
- HNRNPL | c.566G>A p.R189Q | Missense Mutation (SNP) | VAF 26/255 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as rs747401819; called by muse, mutect2, varscan2
- KCNJ10 | c.422C>A p.P141Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63634621; called by muse, mutect2, varscan2
- KCTD3 | c.2315A>G p.Y772C | Missense Mutation (SNP) | VAF 27/213 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.215); catalogued as rs1370755980; called by muse, mutect2, varscan2
- KIF26B | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 22/119 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs778508665; called by muse, mutect2, varscan2
- KISS1 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 146/368 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754159096; called by mutect2, varscan2
- LRP2 | c.4991G>A p.R1664Q | Missense Mutation (SNP) | VAF 60/248 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs142712531; called by muse, mutect2, varscan2
- MAP3K6 | c.866A>T p.D289V | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278850791; called by muse, mutect2
- MEGF8 | c.2797C>T p.R933W (on ENST00000251268 / NM_001271938.2; = p.R866W on NM_001410.3) | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs766562569; called by muse, mutect2, varscan2
- MIS12 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs142272148; called by muse, mutect2, varscan2
- MLXIPL | c.1885C>T p.R629C | Missense Mutation (SNP) | VAF 104/487 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs782303285, COSV57670108; called by muse, mutect2, varscan2
- MYBPC2 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866329567, COSV100731700; called by muse, mutect2
- MYO7A | c.6410G>T p.G2137V | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM971018; called by muse, varscan2
- MYO9B | c.6262C>T p.R2088W | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.663); catalogued as rs756542406, COSV55727256; called by muse, varscan2
- NPHS1 | c.3202G>A p.A1068T | Missense Mutation (SNP) | VAF 42/392 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.926); catalogued as rs146858871; called by muse, mutect2
- NPY2R | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as rs755838016, COSV61527886, COSV61528318; called by muse, mutect2, varscan2
- NRG1 | c.83C>A p.A28E | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as CM133117; called by muse, varscan2
- OR5A1 | c.299G>T p.C100F | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57376343; called by muse, mutect2, varscan2
- OR8B12 | c.818C>A p.S273Y | Missense Mutation (SNP) | VAF 19/184 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV60910856; called by muse, mutect2, varscan2
- PCDH11X | c.189C>A p.F63L | Missense Mutation (SNP) | VAF 100/257 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.925); catalogued as COSV100016346; called by muse, mutect2, varscan2
- PCDH17 | c.469C>G p.H157D | Missense Mutation (SNP) | VAF 104/493 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV100932238; called by muse, mutect2, varscan2
- PCDHA7 | c.1504C>A p.R502S | Missense Mutation (SNP) | VAF 495/1249 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV65347593; called by muse, mutect2, varscan2
- PLCZ1 | c.946C>A p.R316S | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs751593977, COSV56853692; called by muse, mutect2, varscan2
- PXDN | c.3031G>T p.G1011C | Missense Mutation (SNP) | VAF 126/552 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1266666214; called by muse, mutect2, varscan2
- RBFOX1 | c.391C>A p.P131T | Missense Mutation (SNP) | VAF 62/176 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs1429559005; called by muse, mutect2, varscan2
- RUNDC3B | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 46/158 reads (29%) | catalogued as COSV55952063; called by muse, mutect2, varscan2
- SNAPC4 | c.4300G>C p.G1434R | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as COSV100047888; called by muse, mutect2, varscan2
- SPOP | c.50C>A p.P17H | Missense Mutation (SNP) | VAF 37/314 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as COSV61656008; called by muse, mutect2, varscan2
- STON2 | c.2419G>T p.E807* (on ENST00000649389 / NM_001366849.2; = p.E750* on NM_001256430.2 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/252 reads (10%) | catalogued as COSV99964713; called by muse, varscan2
- TENM3 | c.6643C>T p.R2215* | Nonsense Mutation (SNP) | VAF 6/63 reads (10%) | catalogued as COSV69313512; called by muse, mutect2, varscan2
- ZNF765 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 40/299 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV67182887; called by muse, mutect2, varscan2
- ABCA1 | c.3462G>T p.K1154N | Missense Mutation (SNP) | VAF 52/487 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- ABCC9 | c.1320+1G>T p.X440_splice | Splice Site (SNP) | VAF 22/112 reads (20%) | called by muse, mutect2, varscan2
- ABCC9 | c.1320G>T p.Q440H | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ADCY2 | c.529C>A p.L177M | Missense Mutation (SNP) | VAF 149/407 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- ANKRD30BL | c.126C>G p.I42M | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AOX1 | c.568G>C p.E190Q | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.37); PolyPhen benign (0.003); called by muse, mutect2
- ARAP1 | c.2631G>T p.Q877H (on ENST00000393609 / NM_001040118.2; = p.Q632H on NM_015242.4) | Missense Mutation (SNP) | VAF 30/324 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2
- ARHGEF10 | c.2586G>C p.W862C (on ENST00000398564; = p.W837C on NM_014629.4) | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BPIFA2 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 30/364 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.473); called by muse, mutect2
- BSG | c.418G>T p.G140C | Missense Mutation (SNP) | VAF 59/208 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- C1orf167 | c.962G>T p.S321I | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- CAPS2 | c.1101+1G>T p.X367_splice | Splice Site (SNP) | VAF 10/56 reads (18%) | called by muse, mutect2, varscan2
- CD14 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 15/266 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- CDK13 | c.2419G>T p.V807F | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRM2 | c.1397G>C p.R466T | Missense Mutation (SNP) | VAF 43/220 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CMTR2 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COG3 | c.2019G>T p.E673D | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- COL15A1 | c.2950_2950+8del p.X984_splice | Splice Site (DEL) | VAF 14/148 reads (9%) | called by mutect2, pindel
- COL20A1 | c.2385C>A p.H795Q | Missense Mutation (SNP) | VAF 67/336 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- COL24A1 | c.4161del p.Q1388Sfs*10 | Frame Shift Del (DEL) | VAF 34/146 reads (23%) | called by mutect2, pindel, varscan2
- CPSF7 | c.485G>A p.R162Q (on ENST00000394888 / NM_001136040.4; = p.R205Q on NM_024811.4) | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CYLC2 | c.166del p.D56Tfs*6 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | called by mutect2, pindel, varscan2
- DACH2 | c.641-2A>T p.X214_splice | Splice Site (SNP) | VAF 40/101 reads (40%) | called by muse, mutect2
- DACH2 | c.641G>T p.G214V | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DCDC1 | c.1338G>T p.L446F | Missense Mutation (SNP) | VAF 51/143 reads (36%) | SIFT tolerated (0.66); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- DCLK2 | c.1295del p.G432Efs*5 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel, varscan2
- DLL3 | c.649C>G p.P217A | Missense Mutation (SNP) | VAF 45/202 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH3 | c.2698G>A p.A900T | Missense Mutation (SNP) | VAF 37/209 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAI1 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 41/303 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- DPY19L4 | c.1593G>T p.M531I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- FLG | c.2958G>T p.R986S | Missense Mutation (SNP) | VAF 109/784 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- FLRT1 | c.1695C>A p.F565L | Missense Mutation (SNP) | VAF 43/165 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FNIP1 | c.330A>G p.I110M | Missense Mutation (SNP) | VAF 47/113 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FSD1L | c.1023C>A p.G341= | Splice Region (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- FSHB | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 47/385 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FTMT | c.277G>T p.V93L | Missense Mutation (SNP) | VAF 44/228 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- FUT7 | c.799C>A p.P267T | Missense Mutation (SNP) | VAF 57/452 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GGCX | c.1969C>T p.Q657* | Nonsense Mutation (SNP) | VAF 41/358 reads (11%) | called by muse, mutect2, varscan2
- GK3P | c.320C>G p.P107R | Missense Mutation (SNP) | VAF 43/469 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- GOLGA8M | c.451C>A p.H151N | Missense Mutation (SNP) | VAF 122/709 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); called by mutect2, varscan2
- GPR34 | c.1070C>T p.S357L | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- GREB1L | c.4504A>T p.M1502L | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HFM1 | c.1188G>C p.W396C | Missense Mutation (SNP) | VAF 11/162 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- IL1RL1 | c.423G>C p.W141C | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- INPP4B | c.767C>G p.S256* | Nonsense Mutation (SNP) | VAF 14/183 reads (8%) | called by muse, mutect2
- ITGA6 | c.2644C>G p.L882V (on ENST00000442250; = p.L843V on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ITGB2 | c.101G>T p.R34L | Missense Mutation (SNP) | VAF 80/288 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.163); called by muse, mutect2, varscan2
- KMT5B | c.2503G>T p.D835Y | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- L1TD1 | c.149C>G p.A50G | Missense Mutation (SNP) | VAF 17/119 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- LAMA4 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 23/226 reads (10%) | called by muse, mutect2, varscan2
- MUC12 | c.16077T>A p.N5359K (on ENST00000379442; = p.N5216K on NM_001164462.1) | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); called by muse, varscan2
- NBPF11 | c.567-2A>C p.X189_splice | Splice Site (SNP) | VAF 78/966 reads (8%) | called by muse, mutect2
- NCOA6 | c.3580G>T p.G1194C | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- NETO2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- NFATC4 | c.1102_1107del p.S368_R369del | In Frame Del (DEL) | VAF 42/169 reads (25%) | called by mutect2, pindel, varscan2
- OPLAH | c.1986G>T p.M662I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR13C2 | c.532A>T p.T178S | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2
- OR2A42 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 109/240 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- OR2J2 | c.175C>A p.P59T | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- OR4C6 | c.416G>C p.C139S | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR9A4 | c.267G>T p.M89I | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- P2RY10 | c.497del p.P166Hfs*5 | Frame Shift Del (DEL) | VAF 30/75 reads (40%) | called by mutect2, pindel, varscan2
- P2RY12 | c.385C>A p.P129T | Missense Mutation (SNP) | VAF 38/337 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- PCDHA13 | c.334A>T p.R112W | Missense Mutation (SNP) | VAF 202/852 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- PCDHGA7 | c.1629C>G p.S543R | Missense Mutation (SNP) | VAF 164/549 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PDCD7 | c.830G>A p.W277* | Nonsense Mutation (SNP) | VAF 20/460 reads (4%) | called by muse, mutect2
- PIKFYVE | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 49/232 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PLXNA1 | c.5305A>C p.T1769P | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- POLR2B | c.3280C>G p.Q1094E | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.469); called by muse, mutect2
- PPP1R3A | c.2062A>T p.K688* | Nonsense Mutation (SNP) | VAF 105/372 reads (28%) | called by muse, mutect2, varscan2
- PSD3 | c.2739_2740insT p.K914* (on ENST00000440756; = p.K913* on NM_015310.4) | Frame Shift Ins (INS) | VAF 21/118 reads (18%) | called by mutect2, pindel*, varscan2
- PTCHD3 | c.457G>T p.G153C | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RAB11FIP3 | c.783A>T p.Q261H | Missense Mutation (SNP) | VAF 20/216 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAD54L | c.1713del p.S572Afs*70 | Frame Shift Del (DEL) | VAF 75/342 reads (22%) | called by mutect2, pindel, varscan2
- RELN | c.8840C>A p.A2947E | Missense Mutation (SNP) | VAF 25/157 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- REV3L | c.1860A>T p.E620D | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RIPPLY3 | c.373G>C p.E125Q | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.392); called by muse, mutect2
- RUBCN | c.1476G>C p.E492D | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- RYR2 | c.11185G>T p.A3729S | Missense Mutation (SNP) | VAF 26/156 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- SALL3 | c.2266C>A p.Q756K | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SART1 | c.1445C>T p.P482L | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- SAXO1 | c.666T>G p.H222Q | Missense Mutation (SNP) | VAF 39/319 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2, varscan2
- SCAMP1 | c.149G>T p.G50V | Missense Mutation (SNP) | VAF 38/201 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SEC14L3 | c.1139C>A p.T380K | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.04); called by muse, mutect2
- SEC14L3 | c.1137C>A p.F379L | Missense Mutation (SNP) | VAF 45/205 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.025); called by muse, mutect2
- SEPTIN6 | c.573G>C p.K191N | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- SETX | c.875G>T p.C292F | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SFI1 | c.2580G>T p.W860C (on ENST00000400288 / NM_001007467.3; = p.W829C on NM_014775.4) | Missense Mutation (SNP) | VAF 19/125 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC22A7 | c.1507C>A p.L503M (on ENST00000372585 / NM_153320.2; = p.L501M on NM_006672.3) | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- SOX11 | c.147C>G p.I49M | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SPAM1 | c.34A>T p.R12* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- SPATA5L1 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 15/408 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.722); called by muse, mutect2
- SRXN1 | c.58G>T p.E20* | Nonsense Mutation (SNP) | VAF 8/79 reads (10%) | called by muse, mutect2, varscan2
- SUCLG1 | c.595G>C p.V199L | Missense Mutation (SNP) | VAF 23/269 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- TACO1 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 28/555 reads (5%) | SIFT tolerated (0.56); PolyPhen benign (0.029); called by muse, mutect2
- TBC1D31 | c.1525del p.Q509Rfs*15 | Frame Shift Del (DEL) | VAF 23/174 reads (13%) | called by mutect2, pindel, varscan2
- TEX15 | c.7915T>A p.S2639T (on ENST00000256246; = p.S3022T on NM_001350162.2) | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- THBS3 | c.2221C>T p.Q741* | Nonsense Mutation (SNP) | VAF 17/292 reads (6%) | called by muse, mutect2
- TPR | c.3789G>A p.M1263I | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.386); called by muse, mutect2
- TRPM2 | c.3707A>T p.D1236V | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- TRPM6 | c.3946G>T p.D1316Y | Missense Mutation (SNP) | VAF 162/664 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); called by mutect2, varscan2
- UBR7 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2
- USH2A | c.11860C>G p.L3954V | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- USH2A | c.5782C>A p.L1928M | Missense Mutation (SNP) | VAF 165/481 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- VSIR | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 43/326 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- WNK4 | c.586A>T p.T196S | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.438); called by muse, mutect2, varscan2
- WRN | c.2378C>T p.T793I | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.173); called by muse, mutect2
- ZFP82 | c.1366G>T p.G456C | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZFP82 | c.1364G>T p.C455F | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF132 | c.716G>C p.S239T | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.067); called by muse, mutect2
- ZNF440 | c.350G>C p.G117A | Missense Mutation (SNP) | VAF 67/300 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ZNF468 | c.361G>T p.G121C | Missense Mutation (SNP) | VAF 19/148 reads (13%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF496 | c.229A>T p.T77S | Missense Mutation (SNP) | VAF 382/883 reads (43%) | SIFT tolerated (0.11); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- ZNF521 | c.1020C>G p.H340Q | Missense Mutation (SNP) | VAF 31/268 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- ADAM30 | c.2040G>A p.G680= | Silent (SNP) | VAF 27/163 reads (17%) | catalogued as rs765910510; called by muse, mutect2, varscan2
- AP5B1 | c.2460G>T p.V820= | Silent (SNP) | VAF 18/214 reads (8%) | called by muse, mutect2
- CCDC73 | c.1470C>A p.L490= | Silent (SNP) | VAF 44/159 reads (28%) | called by muse, mutect2, varscan2
- CSMD1 | c.10509A>T p.S3503= (on ENST00000520002; = p.S3502= on NM_033225.6) | Silent (SNP) | VAF 12/94 reads (13%) | called by muse, mutect2, varscan2
- DHX30 | c.291G>T p.V97= (on ENST00000445061 / NM_138615.3; = p.V58= on NM_014966.3) | Silent (SNP) | VAF 41/159 reads (26%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.8259C>T p.R2753= | Silent (SNP) | VAF 130/497 reads (26%) | catalogued as rs752418713; ClinVar: likely benign; called by muse, mutect2, varscan2
- EHD2 | c.762C>T p.I254= | Silent (SNP) | VAF 17/120 reads (14%) | catalogued as rs775008579, COSV54407448; called by muse, mutect2, varscan2
- FAM13C | c.888C>A p.L296= | Silent (SNP) | VAF 39/194 reads (20%) | called by muse, mutect2, varscan2
- GAL3ST3 | c.1029G>T p.R343= | Silent (SNP) | VAF 38/115 reads (33%) | called by muse, mutect2, varscan2
- GHRHR | c.1078C>T p.L360= | Silent (SNP) | VAF 75/346 reads (22%) | catalogued as COSV58197092; called by muse, mutect2, varscan2
- GMPPA | c.435C>T p.N145= | Silent (SNP) | VAF 51/229 reads (22%) | called by muse, mutect2, varscan2
- IGKV1D-17 | c.285C>A p.L95= | Silent (SNP) | VAF 133/655 reads (20%) | called by muse, mutect2, varscan2
- LAMA2 | c.2973C>A p.V991= | Silent (SNP) | VAF 115/459 reads (25%) | catalogued as COSV101370609; called by muse, mutect2, varscan2
- LRRC72 | c.801G>A p.E267= | Silent (SNP) | VAF 33/123 reads (27%) | called by muse, mutect2, varscan2
- MUC22 | c.3288C>T p.T1096= | Silent (SNP) | VAF 90/384 reads (23%) | called by muse, mutect2, varscan2
- MYO9B | c.3156G>A p.Q1052= | Silent (SNP) | VAF 19/423 reads (4%) | called by muse, mutect2
- MZF1 | c.1482C>T p.F494= | Silent (SNP) | VAF 29/367 reads (8%) | called by muse, mutect2
- NCAPH2 | c.1467A>T p.T489= | Silent (SNP) | VAF 19/198 reads (10%) | called by muse, mutect2, varscan2
- NOD1 | c.1002A>T p.T334= | Silent (SNP) | VAF 57/264 reads (22%) | called by muse, mutect2, varscan2
- OBSL1 | c.4767G>T p.S1589= | Silent (SNP) | VAF 67/373 reads (18%) | catalogued as COSV99522535; called by muse, mutect2, varscan2
- OR11H6 | c.666G>T p.S222= | Silent (SNP) | VAF 23/150 reads (15%) | called by muse, mutect2, varscan2
- OR13C2 | c.534C>A p.T178= | Silent (SNP) | VAF 22/196 reads (11%) | called by muse, mutect2
- OR13C3 | c.543C>T p.S181= | Silent (SNP) | VAF 50/426 reads (12%) | catalogued as rs779802213, COSV66165902; called by muse, mutect2, varscan2
- OR2AT4 | c.624C>T p.A208= | Silent (SNP) | VAF 21/169 reads (12%) | called by muse, mutect2, varscan2
- OR2T34 | c.642C>A p.T214= | Silent (SNP) | VAF 112/329 reads (34%) | catalogued as COSV60901708; called by muse, mutect2, varscan2
- OR4M1 | c.348A>T p.T116= | Silent (SNP) | VAF 34/375 reads (9%) | called by muse, mutect2
- PDLIM7 | c.414G>T p.P138= | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as rs199782041; called by muse, mutect2, varscan2
- PDZD7 | c.2236C>T p.L746= | Silent (SNP) | VAF 16/69 reads (23%) | called by muse, mutect2, varscan2
- PHF21A | c.1554T>C p.P518= (on ENST00000418153 / NM_001101802.3; = p.P472= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 31/75 reads (41%) | called by muse, mutect2, varscan2
- PLEKHO1 | c.1137G>C p.L379= | Silent (SNP) | VAF 9/235 reads (4%) | catalogued as COSV50309893; called by muse, mutect2
- SCAF11 | c.9G>A p.K3= | Silent (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2, varscan2
- SHISA9 | c.912C>T p.D304= | Silent (SNP) | VAF 10/101 reads (10%) | called by muse, mutect2, varscan2
- SLC3A2 | c.600C>A p.A200= | Silent (SNP) | VAF 38/430 reads (9%) | catalogued as rs921536046, COSV100101314; called by muse, mutect2
- SLC9A6 | c.378A>T p.V126= | Silent (SNP) | VAF 79/184 reads (43%) | called by muse, mutect2, varscan2
- SLC9A6 | c.1419T>C p.Y473= | Silent (SNP) | VAF 74/208 reads (36%) | catalogued as rs782608371; called by muse, mutect2, varscan2
- SRMS | c.1062G>C p.R354= | Silent (SNP) | VAF 25/292 reads (9%) | catalogued as COSV99420435; called by muse, mutect2
- SYMPK | c.2838G>T p.L946= | Silent (SNP) | VAF 125/541 reads (23%) | catalogued as COSV55610886, COSV99842083; called by muse, mutect2, varscan2
- THSD7A | c.4815G>A p.K1605= | Silent (SNP) | VAF 18/106 reads (17%) | called by muse, mutect2, varscan2
- TMCO5A | c.168G>T p.R56= | Silent (SNP) | VAF 26/186 reads (14%) | called by muse, mutect2, varscan2
- TNFSF9 | c.480C>T p.S160= | Silent (SNP) | VAF 100/419 reads (24%) | catalogued as rs778326812, COSV99832429; called by muse, mutect2, varscan2
- TOPORS | c.1644T>C p.G548= | Silent (SNP) | VAF 42/430 reads (10%) | called by muse, mutect2
- TPM1 | c.141A>G p.Q47= | Silent (SNP) | VAF 51/358 reads (14%) | called by muse, mutect2, varscan2
- TRPV3 | c.2190G>T p.L730= | Silent (SNP) | VAF 23/182 reads (13%) | called by muse, mutect2, varscan2
- UNC93A | c.1284G>A p.V428= | Silent (SNP) | VAF 38/409 reads (9%) | catalogued as COSV57806880; called by muse, mutect2
- USP26 | c.726C>T p.N242= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as rs776894017; called by muse, mutect2, varscan2
- XIRP2 | c.9288T>C p.Y3096= (on ENST00000628543; = p.Y3271= on NM_152381.6) | Silent (SNP) | VAF 44/176 reads (25%) | called by muse, mutect2, varscan2
- ZNF473 | c.1881C>T p.A627= | Silent (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- ABR | c.1962-311G>C | Intron (SNP) | VAF 51/171 reads (30%) | called by muse, mutect2, varscan2
- ADGRV1 | chr5:90558783 C>T | 5'Flank (SNP) | VAF 129/333 reads (39%) | called by muse, mutect2, varscan2
- BCHE | c.1685-5184C>A | Intron (SNP) | VAF 11/83 reads (13%) | called by muse, mutect2, varscan2
- BLOC1S5-TXNDC5 | c.372+38312T>A | Intron (SNP) | VAF 13/108 reads (12%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2807C>G | 3'UTR (SNP) | VAF 195/788 reads (25%) | called by muse, mutect2, varscan2
- CHRND | c.*446C>T | 3'UTR (SNP) | VAF 25/215 reads (12%) | called by muse, mutect2
- COL4A1 | c.388-27A>G | Intron (SNP) | VAF 70/324 reads (22%) | called by muse, mutect2, varscan2
- CSF2RB | c.*4C>A | 3'UTR (SNP) | VAF 17/59 reads (29%) | catalogued as COSV99454163; called by muse, mutect2
- FAM107A | c.-13C>A | 5'UTR (SNP) | VAF 30/141 reads (21%) | called by muse, mutect2, varscan2
- FMN2 | c.-128C>A | 5'UTR (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- GOT1L1 | c.116-37C>G | Intron (SNP) | VAF 21/157 reads (13%) | called by muse, mutect2, varscan2
- IL5RA | c.994+2035A>T | Intron (SNP) | VAF 16/184 reads (9%) | called by muse, mutect2
- LHX6 | c.253-26G>T | Intron (SNP) | VAF 19/100 reads (19%) | called by muse, mutect2, varscan2
- MPZ | c.646-33G>T | Intron (SNP) | VAF 24/229 reads (10%) | called by muse, mutect2, varscan2
- MYH16 | n.4536G>A | RNA (SNP) | VAF 36/165 reads (22%) | called by muse, mutect2, varscan2
- NALCN | c.1765-4772G>T | Intron (SNP) | VAF 68/314 reads (22%) | called by muse, mutect2, varscan2
- PCDHA9 | c.2394+47A>G | Intron (SNP) | VAF 71/150 reads (47%) | called by muse, mutect2, varscan2
- PMPCB | c.99+141G>T | Intron (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- PNP | c.*22A>G | 3'UTR (SNP) | VAF 54/462 reads (12%) | called by muse, mutect2, varscan2
- SRM | c.*53G>T | 3'UTR (SNP) | VAF 9/45 reads (20%) | called by muse, varscan2
- TEX35 | c.586+395G>A | Intron (SNP) | VAF 77/402 reads (19%) | called by muse, mutect2, varscan2
- ZNF525 | c.*2945G>C | 3'UTR (SNP) | VAF 21/118 reads (18%) | called by muse, mutect2, varscan2
